Somatic mutation profile of tumor specimen TCGA-D3-A8GE-06A (aliquot TCGA-D3-A8GE-06A-11D-A372-08) from TCGA case TCGA-D3-A8GE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 26.1 years (9,517 days).
Specimen TCGA-D3-A8GE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6ea00ba-0c94-47c4-a7b0-59e05ecdc322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GE-10A (Blood Derived Normal), aliquot TCGA-D3-A8GE-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6b94f77-f3f3-4779-aa8d-e32b7e65bfe8

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.3587A>C p.H1196P | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV99273726; called by muse, mutect2
- KIF13A | c.2519A>C p.E840A | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99437432; called by muse, mutect2
- KIF21B | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144924; called by muse, mutect2
- PLAG1 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100388128; called by muse, mutect2, varscan2
- HCN2 | c.1512T>C p.Y504= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as COSV99242181; called by muse, mutect2
- RNPEP | c.1737C>A p.V579= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV99821779; called by muse, mutect2
